Somatic mutation profile of tumor specimen TCGA-CA-5797-01A (aliquot TCGA-CA-5797-01A-01D-1650-10) from TCGA case TCGA-CA-5797, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.6 years (20,662 days).
Specimen TCGA-CA-5797-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e080311-1882-4a82-8934-bfcd730f00b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-5797-10A (Blood Derived Normal), aliquot TCGA-CA-5797-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523bac88-98e6-4722-a413-d4e474600ea9

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 126/214 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs386833560, CM061016, COSV58679063, COSV58679897; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MYH7 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs397516088, CM031268, COSV62516328, COSV62522137; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 21/28 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 372/782 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV53209492; called by muse, mutect2, varscan2
- ADAM33 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62933657; called by muse, mutect2, varscan2
- ADAMTS18 | c.3564C>A p.C1188* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as COSV51398945, COSV51413476; called by muse, mutect2, varscan2
- ANKFN1 | c.2159T>G p.F720C | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59441175; called by muse, mutect2, varscan2
- APC | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 72/214 reads (34%) | catalogued as CD021190, CM022311, COSV57366795; called by muse, mutect2, varscan2
- APCS | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54818864, COSV99661442; called by muse, mutect2, varscan2
- ARID1A | c.6341C>T p.P2114L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773818181, COSV61371709; called by muse, mutect2, varscan2
- ATP2B3 | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54840617, COSV99683916; called by muse, mutect2, varscan2
- AXIN2 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61057918; called by muse, mutect2, varscan2
- BRCA1 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 29/317 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV58784226; called by muse, mutect2
- BRCC3 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV100341732; called by muse, mutect2
- C12orf60 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV57451039; called by muse, mutect2, varscan2
- CBLIF | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV99951051; called by muse, mutect2, varscan2
- CCDC88B | c.3549G>T p.Q1183H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100105787; called by mutect2, varscan2
- CTNNA2 | c.2713T>A p.S905T (on ENST00000402739 / NM_001282597.3; = p.S857T on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.677); catalogued as COSV100561669; called by muse, mutect2, varscan2
- DCC | c.1771T>A p.F591I | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100497380; called by muse, mutect2, varscan2
- EFCAB6 | c.4366G>A p.V1456I | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV53057721; called by muse, mutect2, varscan2
- EHD1 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958886354, COSV57735538; called by muse, varscan2
- F13B | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV66372324; called by muse, mutect2, varscan2
- H4C7 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs967059166, COSV55100414, COSV55100792; called by muse, mutect2, varscan2
- HERC1 | c.4444G>A p.G1482R | Missense Mutation (SNP) | VAF 115/492 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.11); catalogued as COSV71245975; called by muse, mutect2, varscan2
- IL11RA | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs1269340905; called by muse, mutect2, varscan2
- IPP | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 136/262 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV63431859; called by muse, mutect2, varscan2
- LBP | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99461170; called by muse, mutect2
- LSG1 | c.49A>C p.M17L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99503443; called by muse, mutect2, varscan2
- MMS22L | c.3660T>A p.Y1220* | Nonsense Mutation (SNP) | VAF 80/347 reads (23%) | catalogued as COSV51516795; called by muse, mutect2, varscan2
- MYLK3 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV67362581; called by muse, mutect2, varscan2
- NRXN2 | c.4639C>T p.P1547S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); catalogued as COSV55447353; called by muse, mutect2, varscan2
- OR2M2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs149761766; called by muse, mutect2, varscan2
- OR2M2 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62897799; called by muse, mutect2, varscan2
- PLEKHS1 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1262774996, COSV63054091; called by muse, mutect2, varscan2
- PLSCR4 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 27/550 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100724305; called by muse, mutect2
- PRKG2 | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100020321; called by muse, mutect2
- RASA4 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53550205; called by mutect2, varscan2
- SARS1 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV52319614; called by muse, mutect2, varscan2
- SH3TC2 | c.2332C>A p.H778N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as COSV60460800, COSV60465457; called by muse, mutect2, varscan2
- SI | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1427495882, COSV100014671, COSV52266359; called by muse, mutect2, varscan2
- SLC22A25 | c.1379T>A p.I460N | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100123660, COSV60594537; called by muse, mutect2, varscan2
- SRRM2 | c.4069G>T p.G1357* | Nonsense Mutation (SNP) | VAF 68/180 reads (38%) | catalogued as COSV57068338; called by muse, mutect2, varscan2
- THSD7A | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774611290, COSV70260421, COSV70267749; called by muse, mutect2, varscan2
- TM7SF3 | c.1022C>G p.P341R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100544629, COSV100544955; called by muse, mutect2
- TUBAL3 | c.1025C>T p.T342M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs149687567; called by muse, mutect2, varscan2
- USP24 | c.6535C>T p.R2179W | Missense Mutation (SNP) | VAF 115/261 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV53762065; called by muse, mutect2, varscan2
- ZFP36L2 | c.451_452insA p.S151Yfs*323 | Frame Shift Ins (INS) | VAF 10/53 reads (19%) | catalogued as COSV56697087, COSV56697605; called by mutect2, pindel, varscan2
- AHDC1 | c.3365A>G p.E1122G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by mutect2, varscan2
- APC | c.4063_4064insTTTTT p.S1355Ffs*62 | Frame Shift Ins (INS) | VAF 30/103 reads (29%) | called by mutect2, pindel, varscan2
- ECI1 | c.36_37del p.V13Sfs*75 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by pindel, varscan2
- HNRNPA3 | c.799dup p.Y267Lfs*2 | Frame Shift Ins (INS) | VAF 184/366 reads (50%) | called by mutect2, pindel, varscan2
- TCP11L1 | c.32del p.N11Mfs*30 | Frame Shift Del (DEL) | VAF 64/154 reads (42%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2
- ASH2L | c.1758G>A p.P586= | Silent (SNP) | VAF 86/407 reads (21%) | catalogued as rs781382549, COSV51698528; called by muse, mutect2, varscan2
- AXIN2 | c.1251G>T p.A417= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs557397475, COSV61055300, COSV61055578; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCORL1 | c.1740C>T p.P580= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs746346454, COSV54389791, COSV99498756; called by muse, mutect2, varscan2
- BHLHE40 | c.606G>A p.K202= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV56574684; called by muse, mutect2, varscan2
- CAMSAP3 | c.3189C>T p.L1063= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs777189224, COSV50330892, COSV99350467; called by muse, mutect2, varscan2
- CCKAR | c.1092C>T p.C364= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs758484210, COSV55160028; called by muse, mutect2, varscan2
- CFAP74 | c.1431C>T p.P477= | Silent (SNP) | VAF 38/59 reads (64%) | catalogued as rs1287877837, COSV54564673; called by muse, mutect2, varscan2
- CLPX | c.726G>A p.Q242= | Silent (SNP) | VAF 124/250 reads (50%) | catalogued as COSV55643267; called by muse, mutect2, varscan2
- CRTC2 | c.741C>T p.V247= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV57841128; called by muse, mutect2, varscan2
- GTSE1 | c.222G>A p.P74= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs147042849; called by muse, mutect2, varscan2
- KLHL32 | c.1230C>G p.R410= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV65110506; called by muse, mutect2, varscan2
- PAF1 | c.528C>T p.I176= | Silent (SNP) | VAF 138/296 reads (47%) | catalogued as COSV55392594; called by muse, mutect2, varscan2
- PCDHGA8 | c.300G>A p.P100= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV53900169; called by muse, mutect2, varscan2
- PSD2 | c.2226T>C p.S742= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs548300272, COSV99217422; called by muse, mutect2, varscan2
- RFC5 | c.435C>T p.F145= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV99969980; called by muse, mutect2, varscan2
- SNTG2 | c.1155G>A p.R385= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs763250834, COSV57968692; called by muse, mutect2, varscan2
- STK33 | c.807G>A p.A269= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs557756682, COSV59396639; called by muse, mutect2, varscan2
- ZNF790 | c.180G>A p.G60= | Silent (SNP) | VAF 39/198 reads (20%) | catalogued as COSV100764863; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827705 del T | 3'Flank (DEL) | VAF 409/715 reads (57%) | catalogued as COSV59423144; called by mutect2, pindel, varscan2
